Surgical pathology report (de-identified scan), TCGA case TCGA-61-2098, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2098-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT FALLOPIAN TUBE AND OVARY, 2833 GRAMS, (26.0 X 18.0 X 11.0 CM), RIGHT SALPINGO-OOPHORECTOMY –

- A. MIXED PAPILLARY SEROUS AND ENDOMETRIOID ADENOCARCINOMA WITH FOCAL SQUAMOUS METAPLASIA (DIFFERENTIATION), MODERATELY DIFFERENTIATED WITH EXTENSIVE NECROSIS.
- B. PARAOVARIAN ADHESIONS WITH MESOTHELIAL CELL PROLIFERATION, FOCAL HEMORRHAGE, EDEMA AND CHRONIC INFLAMMATION.
- C. RIGHT FALLOPIAN TUBE FREE OF TUMOR.
- D. TUBOOVARIAN ADHESION WITH CHRONIC INFLAMMATION FREE OF TUMOR.

PART 2: LEFT OVARY AND FALLOPIAN TUBE, 396 GRAMS, (12.5 X 11.5 X 6.5 CM), LEFT SALPINGO-OOPHORECTOMY –

- A. MIXED PAPILLARY SEROUS AND ENDOMETRIOID ADENOCARCINOMA, MODERATELY DIFFERENTIATED WITH FOCAL SQUAMOUS METAPLASIA AND EXTENSIVE NECROSIS.
- B. OVARIAN TISSUE WITH EPITHELIAL INCLUSION CYSTS AND EDEMA.
- C. PARAOVARIAN AND TUBOOVARIAN ADHESION WITH CHRONIC INFLAMMATION, EDEMA AND MESOTHELIAL PROLIFERATION.
- D. LEFT FALLOPIAN TUBE FREE OF TUMOR WITH A SMALL PARATUBAL CYST FREE OF TUMOR.

PART 3: POSTERIOR PERITONEUM, EXCISION –

VASCULARIZED FIBROFATTY TISSUE WITH CHRONIC INFLAMMATION, EDEMA, LYMPHOID FOLLICLES AND MESOTHELIAL PROLIFERATION.

PART 4: UTERUS, 76 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY –

- A. CHRONIC CERVICITIS WITH ATROPHY.
- B. ATROPHIC ENDOMETRIUM WITH CYSTIC CHANGES.
- C. ENDOMETRIAL POLYP WITH CYSTIC CHANGES.
- D. MYOMETRIUM.

PART 5: PORTION OF PERIAORTIC LYMPH NODE –

ONE LYMPH NODE WITH METASTATIC MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE OVARY.

PART 6: OMENTUM, EXCISION –

MATURE ADIPOSE TISSUE WITH CHRONIC INFLAMMATION, MESOTHELIAL PROLIFERATION, LYMPHOID FOLLICLE, MICROCALCIFICATION AND PSAMMOMA BODY FORMATION AND RARE MALIGNANT ADENOCARCINOMA CELL CLUSTER ON THE SURFACE OF THE OMENTAL FAT.

Source: NCI Genomic Data Commons file 0a2aa69f-eb15-4ff9-9017-41f2181b63cf (TCGA-61-2098.D1C8AB49-5BA0-46C3-8205-53B4E39808B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).